CCDI case PBCARV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/8f5d02ea-63cd-43ee-9180-58fb70f18c4b

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Desmoplastic small round cell tumor: ICD-O-3 morphology code: 8806/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 14.9 years (5,460 days).

Biospecimens (2 samples)
- Sample 0DMN1C: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMN25: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
